Somatic mutation profile of tumor specimen TCGA-B1-A654-01A (aliquot TCGA-B1-A654-01A-11D-A31X-10) from TCGA case TCGA-B1-A654, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 43.0 years (15,721 days).
Specimen TCGA-B1-A654-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7576aeb9-69bd-4cb3-aff8-51c7a6f1b77f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B1-A654-10A (Blood Derived Normal), aliquot TCGA-B1-A654-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3cee2c5-cbfb-4584-8668-b89ed548e253

The open-access MAF lists 60 somatic variants for this specimen: 49 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 10, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 2, Intron 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACER1 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV56836565; called by muse, mutect2, varscan2
- ARL1 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55370833; called by muse, mutect2, varscan2
- BARD1 | c.1788del p.K596Nfs*9 | Frame Shift Del (DEL) | VAF 30/71 reads (42%) | catalogued as COSV53612208; called by mutect2, varscan2
- BRCA2 | c.9938A>C p.K3313T | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66337834; called by muse, mutect2, varscan2
- CFAP410 | c.690G>T p.E230D | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.551); catalogued as COSV57395209; called by muse, mutect2, varscan2
- CHL1 | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV56602266; called by muse, mutect2, varscan2
- CRTC2 | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.32); catalogued as COSV57845092; called by muse, mutect2, varscan2
- CTNND2 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as rs367931998, COSV58893133; called by muse, mutect2, varscan2
- CTSB | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as COSV61541127; called by muse, mutect2, varscan2
- DCAF4L2 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.171); catalogued as rs746615027, COSV60481359; called by muse, mutect2, varscan2
- DNAJC27 | c.361C>A p.H121N | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53096327; called by muse, mutect2, varscan2
- ERCC3 | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.498); catalogued as COSV53429007; called by muse, mutect2, varscan2
- FRMD4B | c.2398C>T p.P800S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as COSV68332595; called by muse, mutect2
- FYCO1 | c.3612C>G p.Y1204* | Nonsense Mutation (SNP) | VAF 57/106 reads (54%) | catalogued as COSV56118636; called by muse, mutect2, varscan2
- GLCE | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV55947585; called by muse, mutect2, varscan2
- GSDME | c.386T>A p.I129N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV61652598; called by muse, mutect2, varscan2
- HECW1 | c.2470T>C p.Y824H | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV67837391; called by muse, mutect2, varscan2
- HOXA9 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV58656530; called by muse, mutect2, varscan2
- HSP90AA1 | c.1771C>T p.R591* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV53489551; called by mutect2, varscan2
- INSC | c.406C>A p.R136S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0.094); catalogued as COSV101088602, COSV65412520; called by muse, varscan2
- ITGAD | c.596A>C p.H199P | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66759475; called by muse, mutect2, varscan2
- ITPK1 | c.904T>A p.Y302N | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50898632; called by muse, mutect2, varscan2
- LCAT | c.395C>A p.S132Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV50454351; called by muse, mutect2, varscan2
- MID1IP1 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.665); catalogued as COSV61230993; called by muse, mutect2, varscan2
- MN1 | c.3556G>A p.A1186T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs753939819, COSV56558178; called by muse, mutect2, varscan2
- MRPL11 | c.321G>C p.E107D | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV60599421; called by muse, mutect2, varscan2
- MYO9A | c.4660G>C p.V1554L | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV61855642; called by muse, mutect2, varscan2
- P2RY6 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV62937813; called by muse, mutect2, varscan2
- PKHD1L1 | c.8913C>G p.Y2971* | Nonsense Mutation (SNP) | VAF 48/119 reads (40%) | catalogued as COSV65749981; called by muse, mutect2, varscan2
- POT1 | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62933379; called by muse, mutect2, varscan2
- PPP1R9B | c.1556T>C p.M519T | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV57541812, COSV57542205; called by muse, mutect2, varscan2
- RBMX2 | c.788A>T p.K263M | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV59729763; called by muse, mutect2, varscan2
- RETREG3 | c.833G>T p.R278M | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV53818458; called by muse, mutect2, varscan2
- RPA4 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as COSV61286654; called by muse, mutect2, varscan2
- SCAMP5 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62643952; called by muse, mutect2, varscan2
- SNIP1 | c.691G>C p.A231P | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV56167933; called by muse, mutect2, varscan2
- SPRY2 | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV65701675; called by muse, mutect2, varscan2
- SRGAP1 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61901753; called by muse, mutect2, varscan2
- SYNE1 | c.26044G>T p.G8682W (on ENST00000367255 / NM_182961.4; = p.G8634W on NM_033071.3) | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55066389; called by muse, mutect2
- TMEM104 | c.155T>A p.L52Q | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59111373; called by muse, mutect2, varscan2
- TMEM202 | c.377T>A p.V126D | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV58983425; called by muse, mutect2, varscan2
- USP30 | c.49A>T p.I17F | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57450987; called by muse, mutect2, varscan2
- WDR20 | c.1333A>G p.S445G | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV54474201; called by muse, mutect2, varscan2
- ZNF71 | c.725A>T p.Y242F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV60149485; called by muse, mutect2, varscan2
- ACSBG2 | c.657del p.K220Rfs*21 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- LARS1 | c.372_374del p.E126del (on ENST00000394434 / NM_020117.11; = p.E99del on NM_016460.3) | In Frame Del (DEL) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- PCDHGC5 | c.1826dup p.L610Vfs*18 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- RPS2 | c.138_143dup p.R48_G49dup | In Frame Ins (INS) | VAF 21/50 reads (42%) | called by mutect2, varscan2
- SERPINI2 | c.96_99delinsA p.D32_L33delinsE | In Frame Del (DEL) | VAF 35/76 reads (46%) | called by pindel, varscan2*
- BPHL | c.600C>T p.D200= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as rs945461499, COSV66744305; called by muse, mutect2, varscan2
- CELSR3 | c.174C>T p.G58= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV51092587; called by muse, mutect2, varscan2
- ITPRID2 | c.2484T>C p.T828= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV57475322; called by muse, mutect2, varscan2
- KMT2C | c.4950T>A p.T1650= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as COSV100078410, COSV51483793; called by muse, mutect2, varscan2
- ODR4 | c.309T>C p.D103= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV55218751; called by muse, mutect2, varscan2
- PHYHIPL | c.48C>A p.P16= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV65849729; called by muse, mutect2, varscan2
- POR | c.1719T>C p.D573= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV58694902; called by muse, mutect2, varscan2
- PTCD1 | c.1725C>T p.L575= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV52865038; called by muse, mutect2, varscan2
- SCYL2 | c.2086C>T p.L696= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs1566374678, COSV62570262; called by muse, mutect2, varscan2
- SLC3A1 | c.1659A>G p.Q553= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs1251194565, COSV53218607; called by muse, mutect2, varscan2
- H2BP2 | n.1061+515_1061+516del | Intron (DEL) | VAF 64/126 reads (51%) | called by mutect2, varscan2
